Gene-level copy-number profile of tumor specimen BLGSP-71-06-00286-01A from CGCI case BLGSP-71-06-00286, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 10.1 years (3,680 days).
Specimen BLGSP-71-06-00286-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3674fdfd-b6eb-4205-8708-cfeab1417ce5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00286-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/cc8b690a-c638-4ad8-93bf-0c12427b2550

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 2,505; copy number 2: 55,700; copy number 3: 118.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,146,131, 55 genes (within-gene range 0–1): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13, IGHVIII-13-1, IGHV1-14.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr22:22,886,267–22,886,379, 1 gene (within-gene range 0–1): MIR5571.
- chr22:22,893,692–22,919,851, 12 genes (within-gene range 0–1): IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3, IGLC3, IGLJ4, IGLC4, IGLJ5, IGLC5, IGLJ6, IGLC6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
